Somatic mutation profile of tumor specimen C3N-00150-04 (aliquot CPT0066510008) from CPTAC case C3N-00150, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.5 years (20,286 days).
Specimen C3N-00150-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2049b88-814b-441c-affc-bcce447ab8db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00150-31 (Blood Derived Normal), aliquot CPT0071650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2907bae-641e-4dba-baa3-677583670042

The open-access MAF lists 84 somatic variants for this specimen: 62 protein-altering or splice-affecting, 10 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 10, Intron 6, Frame Shift Del 5, Splice Site 5, 3'UTR 3, Frame Shift Ins 2, 5'UTR 1, RNA 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2341A>G p.M781V | Missense Mutation (SNP) | VAF 36/506 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60799502, COSV60802815; called by muse, mutect2
- ADAMTS10 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 34/602 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV54352128; called by muse, mutect2
- ARAP2 | c.2683C>G p.L895V | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as rs373281502; called by muse, mutect2, varscan2
- CEMIP | c.965-1G>C p.X322_splice | Splice Site (SNP) | VAF 62/385 reads (16%) | catalogued as rs769389649; called by muse, mutect2, varscan2
- CNN2 | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 45/381 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs141801176, COSV99565612; called by muse, mutect2, varscan2
- COL5A1 | c.3961G>A p.G1321R | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1034436638, COSV65665451; called by muse, mutect2
- CTNNA1 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.315); catalogued as rs758284033; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHCR7 | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 77/472 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CM034225; called by muse, mutect2, varscan2
- DMXL2 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757597201; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV57131444; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.212G>T p.C71F | Missense Mutation (SNP) | VAF 59/1406 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs751628118; called by muse, mutect2
- RASGRP4 | c.1477C>G p.R493G | Missense Mutation (SNP) | VAF 59/350 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as COSV53039900, COSV99384963; called by muse, mutect2, varscan2
- RBBP5 | c.222G>T p.W74C | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182081700, COSV52705946; called by muse, mutect2, varscan2
- TRIM38 | c.392A>T p.D131V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as rs1182611170; called by muse, mutect2
- ZDHHC11B | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1175348274; called by muse, varscan2
- ZNF638 | c.3103G>T p.D1035Y | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV52485566; called by muse, mutect2, varscan2
- AACS | c.1881+1G>T p.X627_splice | Splice Site (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2
- ALOX12B | c.1224del p.F409Sfs*6 | Frame Shift Del (DEL) | VAF 60/354 reads (17%) | called by mutect2, pindel, varscan2
- ARAP3 | c.1093+1G>A p.X365_splice | Splice Site (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- ASPSCR1 | c.1348T>G p.F450V | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CCDC153 | c.44A>T p.Q15L | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- CDKN2D | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CERKL | c.1208A>C p.E403A (on ENST00000339098 / NM_001030311.2; = p.E377A on NM_201548.5) | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CNN2 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPLANE1 | c.8423_8424del p.S2808Cfs*9 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- CUL9 | c.1682A>C p.N561T | Missense Mutation (SNP) | VAF 54/390 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CUL9 | c.4687G>T p.G1563C | Missense Mutation (SNP) | VAF 43/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DROSHA | c.2995T>C p.Y999H | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- E2F2 | c.927G>C p.E309D | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ELF3 | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ESF1 | c.164A>C p.K55T | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBLN1 | c.1385A>G p.Q462R | Missense Mutation (SNP) | VAF 104/612 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FYCO1 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- GCGR | c.949-2A>G p.X317_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2
- GRAMD1B | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.993); called by muse, varscan2
- GRB2 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 44/268 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- KMT2A | c.9122_9125del p.I3041Rfs*30 | Frame Shift Del (DEL) | VAF 35/205 reads (17%) | called by mutect2, pindel, varscan2
- L3MBTL2 | c.1051_1052dup p.R352Vfs*24 | Frame Shift Ins (INS) | VAF 38/311 reads (12%) | called by mutect2, pindel, varscan2
- LRBA | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- LRP1B | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK9 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- MYH7B | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.853); called by muse, mutect2
- NAMPT | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRX1 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NPHP3 | c.3847T>A p.L1283I | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PRSS36 | c.1601G>T p.C534F | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTGER2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RAB7A | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2
- RANBP9 | c.1722A>T p.E574D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RTKN | c.1195_1196del p.E399Kfs*18 (on ENST00000272430 / NM_001015055.2; = p.E386Kfs*18 on NM_033046.2) | Frame Shift Del (DEL) | VAF 24/200 reads (12%) | called by mutect2, pindel, varscan2
- SIRT1 | c.1840del p.T614Lfs*7 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel, varscan2
- SLC25A39 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SNAPC4 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SNCG | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SPATA13 | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- TIAL1 | c.372-2A>G p.X124_splice | Splice Site (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- TMEM26 | c.471A>G p.I157M | Missense Mutation (SNP) | VAF 55/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- UGT1A4 | c.354_355insGG p.N119Gfs*20 | Frame Shift Ins (INS) | VAF 50/318 reads (16%) | called by mutect2, pindel, varscan2
- ZBTB4 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF404 | c.1401T>A p.Y467* | Nonsense Mutation (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- ZNF827 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- AMPD3 | c.306C>T p.A102= (on ENST00000396553 / NM_001025389.2; = p.A111= on NM_000480.3) | Silent (SNP) | VAF 71/434 reads (16%) | called by muse, mutect2, varscan2
- CACNA1H | c.2658C>T p.F886= | Silent (SNP) | VAF 56/373 reads (15%) | catalogued as rs1202009471; called by muse, mutect2, varscan2
- CHD8 | c.3091A>C p.R1031= (on ENST00000646647 / NM_001170629.2; = p.R752= on NM_020920.4) | Silent (SNP) | VAF 37/193 reads (19%) | called by muse, mutect2, varscan2
- GRIN3A | c.744T>C p.S248= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1209C>A p.T403= (on ENST00000485419 / NM_001197113.1; = p.T327= on NM_014575.3) | Silent (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- NUP160 | c.1866A>T p.S622= | Silent (SNP) | VAF 32/222 reads (14%) | called by muse, mutect2, varscan2
- REV3L | c.5793T>G p.T1931= | Silent (SNP) | VAF 16/82 reads (20%) | called by muse, varscan2
- SLC1A6 | c.1476C>T p.L492= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV99693773; called by muse, mutect2, varscan2
- TTYH3 | c.174C>T p.L58= | Silent (SNP) | VAF 36/206 reads (17%) | called by muse, mutect2, varscan2
- ZGRF1 | c.378A>T p.P126= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1635+2119C>T | Intron (SNP) | VAF 19/144 reads (13%) | catalogued as rs1213133783; called by muse, mutect2, varscan2
- BTN3A2 | c.937+14C>T | Intron (SNP) | VAF 24/150 reads (16%) | catalogued as rs1439806381; called by muse, mutect2, varscan2
- HBE1 | c.-267+102823G>A | Intron (SNP) | VAF 24/234 reads (10%) | catalogued as rs552504098; called by muse, mutect2, varscan2
- INKA1 | c.-21G>A | 5'UTR (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2
- PHF6 | c.834+63A>G | Intron (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792891 G>C | 3'Flank (SNP) | VAF 52/331 reads (16%) | called by muse, mutect2, varscan2
- RPL13AP20 | n.399A>C | RNA (SNP) | VAF 110/605 reads (18%) | called by muse, mutect2, varscan2
- RTL8B | c.*28G>T | 3'UTR (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- SLC7A13 | c.1180-1001G>T | Intron (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- TMEM169 | c.*11A>T | 3'UTR (SNP) | VAF 51/267 reads (19%) | called by muse, mutect2, varscan2
- WDR61 | c.12+168T>G | Intron (SNP) | VAF 9/197 reads (5%) | called by muse, mutect2
- XIAP | c.*4819T>C | 3'UTR (SNP) | VAF 55/364 reads (15%) | called by muse, mutect2, varscan2
